Somatic mutation profile of tumor specimen TARGET-30-PAMZGT-01A (aliquot TARGET-30-PAMZGT-01A-01W) from TARGET case TARGET-30-PAMZGT, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 1.6 years (602 days).
Specimen TARGET-30-PAMZGT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e1b06c8c-0a22-4ffc-9f1e-bd56c9a387b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAMZGT-10A (Blood Derived Normal), aliquot TARGET-30-PAMZGT-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e4604e1f-6410-400e-943c-74ccdaa33a86

The open-access MAF lists 28 somatic variants for this specimen: 22 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 5, Intron 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARAP1 | c.1598C>A p.S533Y (on ENST00000393609 / NM_001040118.2; = p.S288Y on NM_015242.4) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.659); catalogued as COSV61990132; called by mutect2, varscan2
- CASKIN2 | c.1192G>A p.A398T | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.922); catalogued as COSV58593715; called by muse, mutect2
- CRLF1 | c.173C>A p.A58D | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV101135043, COSV66504301; called by muse, mutect2, varscan2
- FAAH2 | c.457G>T p.A153S | Missense Mutation (SNP) | VAF 20/286 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0.079); catalogued as rs766429868; called by muse, mutect2
- GLIS3 | c.79T>G p.L27V | Missense Mutation (SNP) | VAF 196/632 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.572); catalogued as COSV60925701; called by muse, mutect2, varscan2
- GSTA4 | c.601G>T p.G201C | Missense Mutation (SNP) | VAF 90/283 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63955315; called by muse, mutect2, varscan2
- IL31RA | c.1682G>T p.G561V | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.791); catalogued as COSV51680156; called by muse, mutect2, varscan2
- KIF13A | c.659G>T p.R220L | Missense Mutation (SNP) | VAF 143/276 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV52445579; called by muse, mutect2, varscan2
- LHX4 | c.293C>A p.P98Q | Missense Mutation (SNP) | VAF 45/242 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55373819; called by muse, mutect2, varscan2
- MAN2B1 | c.904G>T p.A302S | Missense Mutation (SNP) | VAF 10/169 reads (6%) | SIFT tolerated (0.74); PolyPhen benign (0.011); catalogued as rs1288920089; called by muse, mutect2
- MYO1D | c.1614-1G>T p.X538_splice | Splice Site (SNP) | VAF 37/159 reads (23%) | catalogued as COSV59009184; called by muse, mutect2, varscan2
- MYO5A | c.1246G>T p.V416L | Missense Mutation (SNP) | VAF 54/338 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV62558000; called by muse, mutect2, varscan2
- PCDHB6 | c.1312C>A p.Q438K | Missense Mutation (SNP) | VAF 24/322 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.011); catalogued as COSV99169920; called by muse, mutect2
- SCG2 | c.1283C>A p.P428Q | Missense Mutation (SNP) | VAF 183/606 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1247924050, COSV59539373; called by muse, mutect2, varscan2
- SGSM1 | c.1552G>T p.G518C | Missense Mutation (SNP) | VAF 79/207 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV68509288; called by muse, mutect2, varscan2
- SPRR1A | c.227C>A p.T76K | Missense Mutation (SNP) | VAF 99/367 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.172); catalogued as rs151244576, COSV61081100; called by muse, mutect2, varscan2
- TNC | c.437G>T p.C146F | Missense Mutation (SNP) | VAF 32/265 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60782071; called by muse, varscan2
- ZNF529 | c.1490A>G p.Q497R | Missense Mutation (SNP) | VAF 41/208 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.66); catalogued as rs1286794936, COSV61899705; called by muse, mutect2, varscan2
- FAT2 | c.8679G>T p.Q2893H | Missense Mutation (SNP) | VAF 63/910 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.364); called by muse, mutect2
- MCM9 | c.244C>T p.Q82* | Nonsense Mutation (SNP) | VAF 8/115 reads (7%) | called by muse, mutect2
- PSMD3 | c.410A>G p.E137G | Missense Mutation (SNP) | VAF 34/196 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- STAG3 | c.2116C>T p.L706F | Missense Mutation (SNP) | VAF 11/209 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- ATP8B1 | c.3690G>A p.K1230= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as COSV52173713; called by muse, mutect2, varscan2
- EXOSC8 | c.417C>T p.L139= | Silent (SNP) | VAF 40/127 reads (31%) | catalogued as COSV53508777, COSV53508860; called by muse, mutect2, varscan2
- MCM9 | c.243C>T p.L81= | Silent (SNP) | VAF 8/118 reads (7%) | catalogued as rs376739285; called by muse, mutect2
- PCDHGB4 | c.1704C>T p.D568= | Silent (SNP) | VAF 6/84 reads (7%) | catalogued as COSV54019285; called by muse, mutect2
- VARS1 | c.1965C>T p.D655= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV63304329; called by muse, mutect2
- MACF1 | c.15832-9820G>T | Intron (SNP) | VAF 21/178 reads (12%) | catalogued as COSV57111567; called by muse, mutect2, varscan2
